CCDI case PBCCEU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/fe37b089-f50c-48e0-a83a-fc5536e075af

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Synovial sarcoma, spindle cell: ICD-O-3 morphology code: 9041/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 6.7 years (2,432 days).

Biospecimens (2 samples)
- Sample 0DPZTR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DPZU9: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
